Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GH, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GH-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Stomach Ca.

GROSS:

Specimen submitted: Distal gastrectomy, unfixed

Measurement: Greater curvature 25.1 cm
Lesser curvature 17.4 cm
Proximal resection margin 18.0 cm
Distal resection margin 4.7 cm
Duodenum 1.2 cm

Tumor location:

Stomach: Middle 1/3 (body), posterior wall
From proximal resection margin - 2.0 cm
From distal resection margin - 13.0 cm

Tumor size: 2.5 x 2.4 cm

Tumor type: EGC I

Gross serosal invasion: No

Representative sections are submitted

Gross photo: Present

Blocks

T1-4, tumor and surrounding tissue x 4

A, antral mucosa x 1

B, body mucosa x 1

P, proximal resection margin x 1

D, distal resection margin x 1

LN1-2, superior gastric lymph nodes x 2

LN3-4, inferior gastric lymph nodes x 2

LN5, '1' lymph nodes x 1

LN6, '4sb' lymph nodes x 1

LN7, '5' lymph nodes x 1

LN8, '6' lymph nodes x 1

LN9, '7' lymph nodes x 1

LN10, '8' lymph nodes x 1

LN11-12, '9' lymph nodes x 2

LN13, '11p' lymph nodes x 1

LN14, '12' lymph nodes x 1

ICD-0-3

adenocarcinoma, tubular 8211/3

Site: Stomach, body C16.2

hw
9/27/12

MICROSCOPIC:

Tumor type: Adenocarcinoma - tubular moderately differentiated

- over -

[page 2 of 2]
Depth of tumor invasion:

T1: T1b-Submucosa upper 1/3 (SM1)

Margins: Proximal resection margin (-)

Distal resection margin (-)

Lauren classification: Intestinal

Ming classification (Growth pattern): Infiltrative

Lymphoid reaction: Absent

Lymphovascular invasion: Present

Venous (large vessel) invasion: Absent

Perineural invasion: Absent

Lymph node metastasis: Absent

SPECIAL STAIN: Cresyl Violet stain reveals no H. pylori.

NOT reported. Gross: .

Stomach, body, scopic, adenocarcinoma

DIAGNOSIS:

Stomach, distal gastrectomy:

Adenocarcinoma, moderately differentiated (early cancer)

Lymph node, perigastric, distal gastrectomy:

Superior gastric: No tumor present (0/9)

Inferior gastric: No tumor present (0/5)

Lymph node, regional, biopsy:

Labeled '1': No lymphoid tissue present

Labeled '4sb': No tumor present (0/2)

Labeled '5': No lymphoid tissue present

Labeled '6': No tumor present (0/7)

Labeled '7': No tumor present (0/4)

Labeled '8': No tumor present (0/2)

Labeled '9': No tumor present (0/9)

Labeled '11p': No tumor present (0/3)

Labeled '12': No lymphoid tissue present

lw
9/20/12

Source: NCI Genomic Data Commons file 75f4500a-a69f-4216-8c3c-0257c0fd09f5 (TCGA-HU-A4GH.0ADF3F92-F4B7-4908-9DF9-15C52F49CB3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).